CPTAC case C3N-00491 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/88e0ed05-4414-44f2-a983-93f7f6c2dc8c

Demographics
Sex at birth: male; Race: white; Year of birth: 1962; Vital status: Dead; Days to death: 99 days; Year of death: 2016; Cause of death: Not Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 54.2 years (19,779 days); Year of diagnosis: 2016; AJCC staging edition: 7th; AJCC clinical M: M1; AJCC pathologic T: T1b; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage IV; Tumor grade: G2; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 99 days; Days to last follow up: 77 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 6.5 cm (a second GDC size field records 6 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved; Sarcomatoid present: No.

Follow-up (2 entries)
- Days to follow up: 77 days; Disease response: Progressive Disease.
- Days to follow up: 77 days; Disease response: With Tumor.

Other clinical attributes
- Weight: 95 kg; Height: 176 cm; BMI: 30.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (6 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-00491-01: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Freezing method: LN2; Initial weight: 289 mg.
- Sample C3N-00491-02: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -13 days; Initial weight: 318 mg; Time between excision and freezing: 18 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3N-00491-03: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Freezing method: LN2; Initial weight: 357 mg.
- Sample C3N-00491-04: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: OCT; Freezing method: LN2; Initial weight: 304 mg.
- Sample C3N-00491-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -13 days; Initial weight: 299 mg; Time between excision and freezing: 18 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-00491-25: Section location: Upper pole; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3N-00491-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -12 days; Method of sample procurement: Blood Draw.
